Somatic mutation profile of tumor specimen TCGA-G5-6572-02A (aliquot TCGA-G5-6572-02A-12D-1826-10) from TCGA case TCGA-G5-6572, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 56.1 years (20,475 days).
Specimen TCGA-G5-6572-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b1a85f1-3127-4ba2-92cd-07bc30d4d5c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G5-6572-10A (Blood Derived Normal), aliquot TCGA-G5-6572-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6c4fc98-1df2-48cf-a484-026a88011f11

The open-access MAF lists 51 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, Nonsense Mutation 4, Frame Shift Ins 3, Splice Region 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 39/129 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1456_1457del p.L486Ifs*6 | Frame Shift Del (DEL) | VAF 26/111 reads (23%) | catalogued as rs587778832; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AASS | c.804T>G p.H268Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.873); catalogued as COSV62790010; called by muse, mutect2, varscan2
- ABCA13 | c.8286G>A p.M2762I | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs1169566311, COSV71287749; called by muse, mutect2, varscan2
- AGBL5 | c.162C>A p.F54L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as COSV59936534; called by muse, mutect2, varscan2
- APC | c.3493A>T p.K1165* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | catalogued as COSV57326930, COSV57341138; called by muse, mutect2, varscan2
- ATP6V1B2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52353641; called by muse, mutect2, varscan2
- CACNA1F | c.2993G>A p.R998Q | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782241013, COSV59904429; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC141 | c.3871T>G p.Y1291D | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.185); catalogued as COSV55373402; called by muse, mutect2, varscan2
- CEP170 | c.2339C>G p.T780S | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770527711, COSV60509032; called by muse, mutect2, varscan2
- CHD6 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 6/102 reads (6%) | catalogued as COSV58557125; called by muse, mutect2
- ERAP1 | c.1979T>A p.L660* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV57087597; called by muse, mutect2, varscan2
- GALNT14 | c.1187G>A p.R396H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs146467165; called by mutect2, varscan2
- HTR6 | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.04); catalogued as COSV57033089; called by muse, mutect2
- IL1RAP | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as COSV50764596; called by muse, mutect2, varscan2
- INTS5 | c.2818C>T p.R940C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV57951528; called by muse, mutect2, varscan2
- JAKMIP1 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746008481, COSV51530389; called by muse, mutect2, varscan2
- KCNJ6 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.443); catalogued as rs780410267, COSV55712309, COSV55714224; called by muse, mutect2, varscan2
- KIAA1217 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200578654, COSV64605675; called by muse, mutect2, varscan2
- KIRREL3 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1485698805, COSV73106129; called by muse, mutect2
- LAMA5 | c.8530G>A p.V2844I | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as rs760179827, COSV53360082; called by muse, varscan2
- MAP3K20 | c.1359G>A p.Q453= | Splice Region (SNP) | VAF 18/101 reads (18%) | catalogued as COSV64378283; called by muse, mutect2, varscan2
- MTHFD1L | c.2029G>C p.V677L | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV66227845; called by muse, mutect2, varscan2
- NLRP14 | c.2418G>C p.L806F | Missense Mutation (SNP) | VAF 58/349 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55067083; called by muse, mutect2, varscan2
- PCDHA4 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs782039700, COSV63541370; called by muse, mutect2, varscan2
- PCDHB5 | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1438588601, COSV50650291, COSV99039329; called by muse, mutect2, varscan2
- POLQ | c.1336C>T p.L446F | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99951428; called by muse, mutect2
- QTRT2 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs376673299; called by muse, mutect2, varscan2
- RAB20 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99940777; called by muse, mutect2
- SYNE1 | c.4165A>G p.T1389A (on ENST00000367255 / NM_182961.4; = p.T1396A on NM_033071.3) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV54980509; called by muse, mutect2, varscan2
- ZC3HAV1 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as COSV54295743; called by muse, mutect2, varscan2
- ZNF263 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs948263417, COSV54596505; called by muse, mutect2, varscan2
- ZNF366 | c.821G>A p.G274D | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV59215531; called by muse, mutect2, varscan2
- NEFH | c.2450dup p.E818Gfs*74 | Frame Shift Ins (INS) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- NOL8 | c.2921dup p.K975Efs*6 | Frame Shift Ins (INS) | VAF 10/82 reads (12%) | called by mutect2, pindel
- TGIF1 | c.69dup p.K24Qfs*13 (on ENST00000330513 / NM_001374396.1; = p.K44Qfs*13 on NM_003244.4) | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS1 | c.702G>T p.P234= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99535762, COSV99536641; called by muse, mutect2, varscan2
- ASPG | c.1401C>G p.G467= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV101496331; called by muse, mutect2
- CDH8 | c.1806C>T p.D602= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs1268371601, COSV54867141, COSV54895067; called by muse, mutect2, varscan2
- CLIC3 | c.246G>A p.L82= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV65406564; called by muse, mutect2, varscan2
- EN2 | c.930C>T p.A310= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs56008230, COSV99818544; called by mutect2, varscan2
- JCAD | c.3282G>A p.V1094= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs569078936, COSV64759607; called by mutect2, varscan2
- JPH4 | c.1143C>T p.A381= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV62508741; called by muse, mutect2
- MEX3B | c.1140C>T p.F380= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV61663434; called by muse, mutect2, varscan2
- NPFFR2 | c.654G>A p.T218= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs141870844; called by muse, mutect2, varscan2
- RYR2 | c.4488C>T p.P1496= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as rs370082063; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- ST3GAL4 | c.807C>A p.A269= (on ENST00000392669 / NM_001254758.1; = p.A265= on NM_006278.3) | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV57107229; called by muse, mutect2, varscan2
- TLN1 | c.1224C>T p.H408= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs201738633, COSV100147192; called by mutect2, varscan2
- TNRC6C | c.2787G>A p.K929= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV56945169; called by muse, mutect2, varscan2
- ZNF549 | c.1716C>G p.L572= (on ENST00000376233 / NM_001199295.2; = p.L559= on NM_153263.2) | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs753469468, COSV99558323; called by muse, varscan2
- CTSL3P | n.219C>T | RNA (SNP) | VAF 5/23 reads (22%) | catalogued as rs141099992; called by muse, mutect2, varscan2
